Somatic mutation profile of tumor specimen 0DVBRN from CCDI case PBCLIN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 9.9 years (3,627 days).
Specimen 0DVBRN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06828a10-4f73-452a-b837-ee739c1b02b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUNP2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ab80fa4-6ce7-4f20-85af-057e1097582b

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Intron 4, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCO2 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 201/374 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs767133207; called by muse, mutect2, varscan2
- CHRNA4 | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 101/368 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs796052323, COSV64718969; called by muse, mutect2, varscan2
- DNAH2 | c.11386C>T p.R3796C | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762729742, COSV101209032; called by muse, mutect2
- H1-2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 62/250 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.753); catalogued as rs781281855, COSV59190279, COSV59190466; called by muse, mutect2, varscan2
- KRT79 | c.1100G>T p.R367L | Missense Mutation (SNP) | VAF 79/294 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57940000, COSV57941402; called by muse, mutect2, varscan2
- LRP4 | c.2911G>A p.A971T | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); catalogued as rs771933495, COSV99059746; called by muse, varscan2
- MBD4 | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 218/396 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.132); catalogued as rs747394347, COSV104375797; called by muse, mutect2, varscan2
- NPHP3 | c.332C>G p.S111C | Missense Mutation (SNP) | VAF 123/198 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs200233813, COSV58129388, COSV58130515; called by muse, mutect2, varscan2
- SLC10A6 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 117/304 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775035778, COSV56722282; called by muse, mutect2, varscan2
- ZNF181 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 76/404 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); catalogued as rs778812128, COSV67626360; called by muse, mutect2, varscan2
- ASH1L | c.8399A>T p.N2800I (on ENST00000368346 / NM_001366177.2; = p.N2795I on NM_018489.3) | Missense Mutation (SNP) | VAF 20/530 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- CFLAR | c.551A>G p.N184S | Missense Mutation (SNP) | VAF 132/357 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.395); called by mutect2, varscan2
- GALNT5 | c.2273A>T p.E758V | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2
- MAP3K9 | c.1001+1del p.X334_splice | Splice Site (DEL) | VAF 60/182 reads (33%) | called by mutect2, varscan2
- NR2F6 | c.1063C>A p.L355M | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC22A31 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); called by muse, mutect2
- SPATA31D1 | c.2440G>T p.G814W | Missense Mutation (SNP) | VAF 53/253 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- TERF2IP | c.716T>G p.V239G | Missense Mutation (SNP) | VAF 86/331 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, varscan2
- ACAT2 | c.55+45C>A | Intron (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- BAHD1 | c.2053-52del | Intron (DEL) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- LIMD2 | c.42+31dup | Intron (INS) | VAF 34/112 reads (30%) | catalogued as rs772621547; called by mutect2, varscan2
- PSTPIP1 | c.-51C>A | 5'UTR (SNP) | VAF 60/234 reads (26%) | called by muse, mutect2, varscan2
- USH1C | c.1285-7506A>G | Intron (SNP) | VAF 66/396 reads (17%) | called by muse, mutect2, varscan2
